Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4760, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4760-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Two left renal masses.

Specimens Submitted:

- 1: SP: Tumor interpolar region left kidney
- 2: SP: Lower pole tumor, left kidney
- 3: SP: Cyst wall interpolar region left kidney
- 4: SP: Left perinephric fat- lower pole
- 6: SP: Supra tumor interpolar region
- 8: SP: Left renal sinus fat
- 7: SP: Left lower pole fat

DIAGNOSIS:

- 1) KIDNEY, INTERPOLAR REGION, LEFT, PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, NUCLEAR GRADE II/IV.
- THE TUMOR GREATEST DIAMETER IS 2.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) KIDNEY, LOWER POLE, LEFT, PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE, CYSTIC, NUCLEAR GRADE II/IV.
- THE TUMOR GREATEST DIAMETER IS 2.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 3) KIDNEY, INTERPOLAR REGION CYST WALL, LEFT, EXCISION:
- FRAGMENTS OF MULTILOCULAR CYSTIC RENAL CELL CARCINOMA.
- 4) KIDNEY, LOWER POLE, PERINEPHRIC FAT, LEFT, EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 5) KIDNEY, LEFT, SUPRA TUMOR, INTERPOLAR REGION, EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 6) KIDNEY, LEFT, RENAL SINUS FAT, LEFT, EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- 7) KIDNEY, LOWER POLE, FAT, LEFT, EXCISION:
- BENIGN FIBROADIPOSE TISSUE.

[page 2 of 3]
[REDACTED]

1) The specimen is received fresh for frozen section, labeled "Tumor interpolar region left kidney". It consists of a 4.0 x 2.0 x 1.5 cm partial nephrectomy specimen. The cut surface reveals a 2.0- x 1.5 x 1.4 cm circumscribed multilobulated, tan-yellow to gray-white mass adjacent to 1.0 cm segment of normal kidney parenchyma. The outer surface is inked black. A specimen is submitted for frozen section. A specimen is also submitted for [REDACTED]. Representative sections are submitted.

Summary of Sections:

FSC - frozen section control

T - multiple sections of tumor including capsule and normal kidney

[REDACTED]

2) The specimen is received fresh for frozen section, labeled "Lower pole tumor, left kidney". It consists of a 2.5 x 2.0 x 1.5 cm tan-pink nodule. The specimen is inked and sectioned revealing a circumscribed, partly cystic mass with tan-pink, friable cut surface and minimal rim of normal kidney. Representative sections are submitted. [REDACTED] is also taken for this.

Summary of Sections:

FSC - frozen section control

T - multiple sections of tumor

[REDACTED]

3) The specimen is received fresh for frozen section, labeled "Cyst wall interpolar region left kidney". It consists of two soft tissues measuring 2.1 x 2.0 x 3.0 cm in aggregate. The entire specimen is submitted for frozen section.

Summary of Sections:

FSC - frozen section control

[REDACTED]

4) The specimen is received in formalin, labeled "Left perinephric fat-lower pole". It consists of a 5.0 x 4.0 x 2.0 cm aggregate of tan-yellow lobulated fatty tissue. No masses are identified or palpated. Representative sections are submitted.

Summary of Sections:

PNF - perinephric fat

[REDACTED]

5) The specimen is received in formalin, labeled "Supra tumor interpolar region". It consists of an 8.0 x 2.0 x 1.0 cm tan-yellow lobulated fatty tissue with probable palpable lymph nodes. All lymph nodes are submitted.

Summary of Sections:

PLN - possible lymph nodes

BLN - bisected lymph nodes

[REDACTED]

6) The specimen is received in formalin, labeled "Left renal sinus fat". It consists of a 6.0 x 4.0 x 2.0 cm aggregate of tan-yellow lobulated fatty tissue. Representative sections are submitted.

Summary of Sections:

RSF - renal sinus fat

[REDACTED]

7) The specimen is received in formalin, labeled "Left lower pole fat". It consists of a 7.0 x 6.0 x 2.5 cm aggregate of lobulated fibrofatty tissue. No masses are grossly palpated. Representative sections are submitted.

Summary of Sections:

[page 3 of 3]
[REDACTED]

LPF - lower pole fat

Summary of Sections:

Part 1: SP: Tumor Interpolar region left kidney [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
5	t	5

Part 2: SP: Lower pole tumor, left kidney [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
5	t	5

Part 3: SP: Cyst wall Interpolar region left kidney [REDACTED]

Block	Sect. Site	PCs
1	fsc	1

Part 4: SP: Left perinephric fat- lower pole [REDACTED]

Block	Sect. Site	PCs
3	pnf	3

Part 5: SP: Supra tumor Interpolar region [REDACTED]

Block	Sect. Site	PCs
2	bln	2
5	pln	5

Part 6: SP: Left renal sinus fat [REDACTED]

Block	Sect. Site	PCs
4	rsf	4

Part 7: SP: Left lower pole fat [REDACTED]

Block	Sect. Site	PCs
4	lpf	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. INKED MARGIN FREE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. INKED MARGIN BENIGN. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: CYSTIC RENAL CORTICAL LESION SUSPICIOUS FOR RENAL CORTICAL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file f7551de3-60ca-437e-8108-11537c9461a0 (TCGA-BP-4760.4701F631-C963-4B33-8E6D-9431C0D7BDD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).